Somatic mutation profile of tumor specimen 0DTVG7 from CCDI case PBCHUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Retina; Age at diagnosis: 1.3 years (468 days).
Specimen 0DTVG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8079e1fe-eaed-47ea-99e4-5e3239e11856.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTVGA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8212aaaf-a0d7-4561-a0a7-429422376120

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RRBP1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 84/1658 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as rs375344957; called by muse, mutect2
- CLCN7 | c.738+89G>T | Intron (SNP) | VAF 63/183 reads (34%) | called by muse, mutect2, varscan2
- VGF | c.-17C>T | 5'UTR (SNP) | VAF 9/166 reads (5%) | catalogued as rs1051214566; called by muse, mutect2
